Somatic mutation profile of tumor specimen TARGET-10-PAPDRP-09A (aliquot TARGET-10-PAPDRP-09A-01D) from TARGET case TARGET-10-PAPDRP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,679 days).
Specimen TARGET-10-PAPDRP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 907a6dec-e6e3-4948-9bb4-d9ee36954be6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDRP-10A (Blood Derived Normal), aliquot TARGET-10-PAPDRP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8b93017-ce8b-42b5-bae5-cde55b694fea

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNA3 | c.2431G>T p.A811S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs914110946; called by muse, mutect2
- CYP11A1 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141235847, COSV51435563; called by muse, mutect2, varscan2
- DTNA | c.2147G>A p.R716Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.372); catalogued as rs371303988, COSV52017967; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FARP1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs200051893, COSV60336861; called by muse, mutect2, varscan2
- KRT33B | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV99290538; called by muse, mutect2, varscan2
- PXDN | c.3928C>T p.R1310W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs373843757; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1193A>G p.E398G | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ID2 | c.401del p.G134Afs*3 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by pindel*, varscan2
- ROCK2 | c.2536G>T p.A846S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- DST | c.19152C>T p.G6384= (on ENST00000361203 / NM_001374722.1; = p.G4081= on NM_015548.5) | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs778633532; called by muse, mutect2, varscan2
- L3MBTL4 | c.1110G>A p.L370= | Silent (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- LAMC2 | c.1233C>A p.G411= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- LFNG | c.582-42G>A | Intron (SNP) | VAF 11/38 reads (29%) | catalogued as rs777343919; called by muse, mutect2, varscan2
